TCGA case TCGA-MQ-A4LI — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/340fef21-55d8-433f-b00a-51276b849356

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 572 days (1.6 years).

Diagnoses (3)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 60.1 years (21,951 days); Year of diagnosis: 1999; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine Hydrochloride.
   Treatment given: Treatment type: Chemotherapy.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 61.2 years (22,367 days); Days to diagnosis: 416 days (1.1 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Abdomen, NOS. Age at diagnosis: 61.2 years (22,367 days); Days to diagnosis: 416 days (1.1 years); Prior treatment: Yes.

Follow-up (4 entries)
- Day 416 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 416 days (1.1 years).
- Day 416 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Thorax, NOS; Days to progression: 416 days (1.1 years).
- Days to follow up: 572 days (1.6 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Exposures
- Exposure type: Asbestos.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MQ-A4LI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 320 mg.
  Slide TCGA-MQ-A4LI-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-MQ-A4LI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Drug treatment 3: Pharmaceutical therapy drug name: Gemzar.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 572 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 572 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 416 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MQ-A4LI-01A-11D-A34B-01): tumor purity 0.75, ploidy 1.78, whole-genome doublings 0.
